Surgical pathology report (de-identified scan), TCGA case TCGA-AP-A0LP, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MSKCC, specimen TCGA-AP-A0LP-01A (Primary Tumor).

[page 1 of 3]
ICD-0-3

Specimens Submitted:

- 1: SP: Uterus, cervix, bilateral tubes and ovaries (
- 2: SP: Rt. external iliac lymph nodes
- 3: SP: Rt. hypogastric lymph nodes
- 4: SP: Rt. obturator lymph nodes
- 5: SP: Lt. external iliac lymph nodes
- 6: SP: Lt. hypogastric lymph nodes
- 7: SP: Lt. obturator lymph nodes (
- 8: SP: Lt. common iliac lymph nodes
- 9: SP: Lt. para-aortic lymph nodes (
- 10: SP: Rt. common iliac lymph nodes
- 11: SP: Rt. para-aortic lymph nodes (

adenocarcinoma, endometrioid, Nos 8380/3
Site: endometrium C54.1

lw
5/1/11

DIAGNOSIS:

- 1) UTERUS, OVARIES AND FALLOPIAN TUBES; TOTAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY:
- ADENOCARCINOMA OF ENDOMETRIUM, ENDOMETRIOID TYPE, NOS, FIGO GRADE I, (<= 6% SOLID GROWTH), NUCLEAR GRADE 2.
- THE TUMOR INVADES TO <= HALF OF MYOMETRIUM.
- THE MAXIMAL THICKNESS OF MYOMETRIAL INVASION IS 2.5 MM.
- THE THICKNESS OF THE MYOMETRIUM IN THE AREA OF MAXIMAL TUMOR INVASION IS 21 MM.
- NO ENDOCERVICAL INVASION IS IDENTIFIED.
- VASCULAR INVASION IS PRESENT.
- THE ENDOMETRIUM SHOWS ATROPHY AND POLYP.
- THE MYOMETRIUM SHOWS ADENOMYOSIS AND LEIOMYOMAS.
- THE RIGHT OVARY SHOWS ENDOSALPINGIOSIS.
- THE LEFT FALLOPIAN TUBE SHOWS ENDOSALPINGIOSIS AND SIMPLE CYSTS.
- ALL OTHER ADNEXAE ARE UNREMARKABLE.
- 2) LYMPH NODES, RIGHT EXTERNAL ILIAC; BIOPSY:
- TWO BENIGN LYMPH NODES (0/2).
- 3) LYMPH NODES, RIGHT HYPOGASTRIC; BIOPSY:
- BENIGN ADIPOSE TISSUE.

** Continued on next page **

[page 2 of 3]
- NO LYMPH NODES ARE IDENTIFIED IN THE ENTIRELY SUBMITTED SPECIMEN.

- 4) LYMPH NODES, RIGHT OBTURATOR; BIOPSY:
- SIX BENIGN LYMPH NODES (0/6).
- 5) LYMPH NODE, LEFT EXTERNAL ILIAC; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 6) LYMPH NODE, LEFT HYPOGASTRIC; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 7) LYMPH NODES, LEFT OBTURATOR; BIOPSY:
- FIVE BENIGN LYMPH NODES (0/5).
- 8) LYMPH NODE, LEFT COMMON ILIAC; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 9) LYMPH NODES, LEFT PARA-AORTIC; BIOPSY:
- SEVEN BENIGN LYMPH NODES (0/7).
- 10) LYMPH NODE, RIGHT COMMON ILIAC; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 11) LYMPH NODES, RIGHT PARA-AORTIC; BIOPSY:
- THREE BENIGN LYMPH NODES (0/3).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 3 of 3]
Procedures/Addenda:
Addendum

Addendum Diagnosis
ADDENDUM

SITE: LYMPH NODES, RIGHT HYPOGASTRIC, BIOPSY
PART #3.
- ADDITIONAL DEEPER SECTIONS FAILED TO REVEAL ANY LYMPH NODES.

** Continued on next page **

Source: NCI Genomic Data Commons file bce5fee0-6d20-40f9-8fda-0e1a52e1747c (TCGA-AP-A0LP.ECA6E3D1-141B-4DB1-90B6-FE6A2E355AD3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).